Somatic mutation profile of tumor specimen C3N-02070-01 (aliquot CPT0109890007) from CPTAC case C3N-02070, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.9 years (20,054 days).
Specimen C3N-02070-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a83105-2af1-42d2-9c52-af841da3b192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02070-71 (Blood Derived Normal), aliquot CPT0146220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d38f9e47-c941-4232-943c-92ad969f5a30

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, Intron 3, 3'UTR 1, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.408del p.F136Lfs*23 | Frame Shift Del (DEL) | VAF 53/155 reads (34%) | catalogued as rs397516442, COSV56544566, COSV56552648; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNPTG | c.858del p.R288Efs*46 | Frame Shift Del (DEL) | VAF 207/758 reads (27%) | catalogued as COSV99201404; called by mutect2, pindel, varscan2
- HBA1 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 190/762 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM004924; called by muse, mutect2, varscan2
- KRTAP5-3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs369891803; called by muse, mutect2
- MYH8 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 26/304 reads (9%) | catalogued as rs1449105624, COSV67963501; called by muse, mutect2
- MYO5C | c.1997T>C p.I666T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs1402795053; called by muse, mutect2
- PBRM1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV56312097; called by muse, mutect2, varscan2
- PCF11 | c.1751A>C p.N584T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV53528037, COSV53537357; called by muse, varscan2
- PROC | c.1285C>A p.L429I | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as CM961166; called by muse, mutect2, varscan2
- PRPS1L1 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218469939, COSV72649826; called by muse, mutect2, varscan2
- SPEN | c.7111G>T p.E2371* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV101005400; called by muse, mutect2, varscan2
- ACSM2A | c.597T>C p.N199= (on ENST00000219054; = p.N120= on NM_001308169.2) | Splice Region (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2
- AKAP7 | c.745A>C p.S249R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ANO2 | c.214G>T p.D72Y (on ENST00000356134 / NM_001278597.3; = p.D76Y on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- ATAD3A | c.1187T>G p.I396S | Missense Mutation (SNP) | VAF 128/440 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ATP13A2 | c.3236-1G>A p.X1079_splice | Splice Site (SNP) | VAF 22/424 reads (5%) | called by muse, mutect2
- C1QL2 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- CLRN3 | c.474A>T p.E158D | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL27A1 | c.1085C>A p.T362N | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.135); called by muse, mutect2
- DOT1L | c.1600A>T p.S534C | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- EPHB6 | c.2054T>G p.V685G | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK1 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB3 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KCNU1 | c.2672T>C p.L891P | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KIAA2012 | c.2973G>C p.E991D | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.01); called by muse, mutect2
- LY6G5B | c.370del p.L124Wfs*17 | Frame Shift Del (DEL) | VAF 51/224 reads (23%) | called by mutect2, pindel, varscan2
- NF1 | c.4391T>G p.F1464C (on ENST00000358273 / NM_001042492.3; = p.F1443C on NM_000267.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NUCB1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- NUDT22 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 110/408 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NUMBL | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2
- NUP214 | c.4781C>G p.T1594S | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- PDIA4 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- PPP1R9B | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1356+1G>T p.X452_splice | Splice Site (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2525T>A p.L842H | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, varscan2
- SFPQ | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SI | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SREK1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- TECTA | c.5827A>T p.K1943* | Nonsense Mutation (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- TET1 | c.4462-1G>A p.X1488_splice | Splice Site (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2
- TFDP1 | c.12+4_12+7del p.X4_splice | Splice Site (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- TNRC6C | c.4447C>T p.P1483S | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRMT1L | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM5 | c.1280T>A p.L427Q | Missense Mutation (SNP) | VAF 15/459 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC5B | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZNF462 | c.5035T>C p.Y1679H | Missense Mutation (SNP) | VAF 101/335 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASTL | c.522G>A p.Q174= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs575107981, COSV60903936; called by muse, mutect2, varscan2
- CNNM4 | c.471C>T p.D157= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as COSV100998749; called by muse, mutect2
- FLRT1 | c.792C>T p.P264= | Silent (SNP) | VAF 66/220 reads (30%) | called by muse, mutect2, varscan2
- FNDC1 | c.2400G>A p.Q800= | Silent (SNP) | VAF 72/252 reads (29%) | called by muse, mutect2, varscan2
- HHLA1 | c.1569C>T p.C523= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- HIBADH | c.882C>T p.T294= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- IQSEC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 14/275 reads (5%) | catalogued as COSV56221792; called by muse, mutect2
- LOXHD1 | c.5154C>G p.T1718= (on ENST00000642948; = p.T607= on NM_001145472.3) | Silent (SNP) | VAF 20/444 reads (5%) | called by muse, mutect2
- MTOR | c.3429G>T p.T1143= | Silent (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- RFC1 | c.1011C>G p.A337= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs765086007, COSV62899932; called by muse, mutect2, varscan2
- RRP8 | c.678C>T p.P226= | Silent (SNP) | VAF 22/227 reads (10%) | called by muse, mutect2
- SLC2A3 | c.228C>T p.I76= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as rs761849988; called by muse, mutect2, varscan2
- TUBA4A | c.849C>T p.H283= | Silent (SNP) | VAF 31/347 reads (9%) | catalogued as rs149475041; called by muse, mutect2
- USP48 | c.2898T>C p.F966= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ZNF264 | c.1881G>C p.L627= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- FNIP2 | c.655+130A>G | Intron (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- MIF4GD | chr17:75272347 G>A | 5'Flank (SNP) | VAF 101/353 reads (29%) | catalogued as rs1318687132; called by muse, mutect2, varscan2
- MPRIP | c.2163+3392C>G | Intron (SNP) | VAF 44/159 reads (28%) | catalogued as rs924014342; called by muse, mutect2, varscan2
- PATJ | c.*17_*18del | 3'UTR (DEL) | VAF 40/153 reads (26%) | called by mutect2, pindel, varscan2
- SERPINA6 | c.-19-11T>C | Intron (SNP) | VAF 12/314 reads (4%) | catalogued as rs1379463594; called by muse, mutect2
- SLC39A3 | chr19:2732277 C>A | 3'Flank (SNP) | VAF 37/323 reads (11%) | called by muse, mutect2, varscan2
